Somatic mutation profile of tumor specimen TCGA-78-7154-01A (aliquot TCGA-78-7154-01A-11D-2036-08) from TCGA case TCGA-78-7154, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 72.5 years (26,481 days).
Specimen TCGA-78-7154-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c5a8417-312f-4584-abb8-2afc0ff976f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7154-10A (Blood Derived Normal), aliquot TCGA-78-7154-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f22ba12-9cf9-4b68-9561-8096d2d46355

The open-access MAF lists 270 somatic variants for this specimen: 179 protein-altering or splice-affecting, 82 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 156, Silent 82, Nonsense Mutation 7, Splice Region 7, RNA 5, Frame Shift Ins 3, Splice Site 3, 5'UTR 2, 3'UTR 2, Translation Start Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060501191, COSV52666332, COSV52700326, COSV52746468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- A4GNT | c.704G>C p.W235S | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV52628774; called by muse, mutect2, varscan2
- ACIN1 | c.3550C>A p.R1184S | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.7); catalogued as COSV52975362; called by muse, mutect2, varscan2
- ADGRL2 | c.1699G>T p.E567* | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as COSV54652660, COSV54663391; called by muse, mutect2, varscan2
- ADGRL3 | c.1687G>A p.E563K (on ENST00000506720 / NM_001322402.2; = p.E495K on NM_015236.6) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as rs759065083, COSV72229254; called by muse, mutect2, varscan2
- ADPRS | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs1425533993, COSV52880753; called by muse, varscan2
- AKAP11 | c.4744C>G p.L1582V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.84); catalogued as COSV50295654; called by muse, mutect2, varscan2
- ALDH16A1 | c.1640T>A p.I547N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53193641; called by muse, mutect2, varscan2
- ALG10B | c.1151T>C p.I384T | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as COSV58142982; called by muse, mutect2, varscan2
- ALK | c.646C>G p.L216V | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.297); catalogued as rs1035402110, COSV66564819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPK3 | c.4834C>T p.Q1612* | Nonsense Mutation (SNP) | VAF 125/270 reads (46%) | catalogued as COSV51932449; called by muse, mutect2, varscan2
- ANAPC4 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.688); catalogued as rs371711389; called by muse, mutect2, varscan2
- ANK3 | c.3821C>T p.S1274F (on ENST00000280772 / NM_001320874.2; = p.S408F on NM_001149.3) | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55053591; called by muse, mutect2, varscan2
- ANKRD30A | c.4033G>A p.D1345N (on ENST00000611781; = p.D1289N on NM_052997.2) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV64608500; called by muse, mutect2, varscan2
- ANO4 | c.2174T>C p.I725T (on ENST00000392977 / NM_001286615.2; = p.I690T on NM_178826.4) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200708403, COSV54592850; called by muse, mutect2, varscan2
- ARHGEF4 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs201247468, COSV58120957; called by muse, mutect2
- ASB4 | c.334C>A p.H112N | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57507827, COSV57509182; called by muse, mutect2, varscan2
- ATP10D | c.180C>G p.F60L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV56706566; called by muse, mutect2, varscan2
- BCL9 | c.1324C>A p.P442T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV52343072; called by muse, mutect2, varscan2
- BIRC6 | c.13348C>T p.R4450C | Missense Mutation (SNP) | VAF 45/73 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777387724, COSV70198135; called by muse, mutect2, varscan2
- BOD1L1 | c.5195C>G p.A1732G | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs1336841497, COSV50009785; called by muse, mutect2, varscan2
- C12orf45 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.373); catalogued as rs749580288, COSV55012662; called by muse, mutect2, varscan2
- C2orf78 | c.1033C>T p.L345F | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.048); catalogued as COSV68517245; called by muse, mutect2, varscan2
- CAPN5 | c.1824C>G p.F608L (on ENST00000456580; = p.F568L on NM_004055.5) | Missense Mutation (SNP) | VAF 81/108 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53687201; called by muse, mutect2, varscan2
- CCDC148 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51758522; called by muse, mutect2
- CCDC186 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV65161036; called by muse, mutect2
- CDAN1 | c.2802G>A p.R934= | Splice Region (SNP) | VAF 21/69 reads (30%) | catalogued as COSV62331652; called by muse, mutect2, varscan2
- CDK12 | c.793A>C p.S265R | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV71000265; called by muse, mutect2
- CDK17 | c.730G>C p.D244H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54128326, COSV99702638; called by muse, mutect2, varscan2
- CDS2 | c.517C>G p.L173V | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66896139, COSV66896446; called by muse, mutect2, varscan2
- CEP76 | c.1039G>C p.G347R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.406); catalogued as COSV50866121, COSV50867193; called by muse, mutect2, varscan2
- CHUK | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV64917656; called by muse, mutect2, varscan2
- CILP | c.297G>T p.W99C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56023400; called by muse, mutect2, varscan2
- COL5A2 | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100881002, COSV66408865; called by muse, mutect2, varscan2
- CSMD3 | c.7273C>T p.P2425S (on ENST00000297405 / NM_001363185.1; = p.P2321S on NM_052900.3) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52156041; called by muse, mutect2
- CYP2C19 | c.220A>G p.M74V | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV64907491; called by muse, mutect2, varscan2
- CYP4F3 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 78/108 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as rs1431626235, COSV55409060; called by muse, mutect2, varscan2
- DAAM1 | c.2777C>G p.S926C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62835701; called by muse, mutect2, varscan2
- DAB2 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV57913802; called by muse, mutect2, varscan2
- DISP1 | c.1717G>A p.D573N | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.974); catalogued as COSV52657597; called by muse, mutect2, varscan2
- DNAH3 | c.3872C>A p.S1291Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.629); catalogued as COSV54516177, COSV54524384; called by muse, mutect2, varscan2
- DNHD1 | c.751C>G p.Q251E | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV54433892; called by muse, mutect2, varscan2
- DOCK3 | c.938A>G p.Y313C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1172317828, COSV56515714; called by muse, mutect2, varscan2
- DONSON | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV51655508; called by muse, mutect2, varscan2
- DPP6 | c.1738G>A p.E580K (on ENST00000377770 / NM_001364500.2; = p.E518K on NM_001936.5) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV59607747; called by muse, mutect2
- ELAC2 | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62032384; called by muse, mutect2, varscan2
- EYA4 | c.329C>A p.A110D | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as COSV62050069, COSV62051060; called by muse, mutect2
- EYS | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV100676429, COSV60982715; called by muse, mutect2, varscan2
- FAM210A | c.62A>G p.H21R | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.01); catalogued as COSV59183997; called by muse, mutect2, varscan2
- FANCD2 | c.3926G>T p.C1309F | Missense Mutation (SNP) | VAF 124/290 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV55036308; called by muse, varscan2
- FAR2 | c.363C>G p.L121= | Splice Region (SNP) | VAF 10/162 reads (6%) | catalogued as COSV51724185, COSV99479114; called by muse, mutect2
- FAT2 | c.7111G>C p.D2371H | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55817875; called by muse, mutect2, varscan2
- FBXL20 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV52898226; called by muse, mutect2, varscan2
- FKBP4 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV99133823; called by muse, mutect2, varscan2
- FLCN | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.042); catalogued as rs369115472, COSV99550801; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMN2 | c.5058G>A p.E1686= | Splice Region (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100145410, COSV100147484, COSV60426905; called by muse, mutect2, varscan2
- FNBP1 | c.949T>G p.S317A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV63086518; called by muse, mutect2, varscan2
- GLIS1 | c.1327C>A p.P443T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as COSV56544659, COSV56547293; called by muse, mutect2, varscan2
- GLRA3 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV56860371; called by muse, mutect2, varscan2
- GPC6 | c.1327C>A p.Q443K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65507362; called by muse, mutect2, varscan2
- GPRC5D | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs777265161, COSV57432579; called by muse, mutect2, varscan2
- GRIA4 | c.952C>A p.Q318K | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.05); catalogued as COSV56891304; called by muse, mutect2
- HCN4 | c.3488C>A p.P1163H | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs756052150, COSV56082854; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HECW1 | c.2861C>T p.A954V | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as rs767085890, COSV67827088; called by muse, mutect2, varscan2
- HERC2 | c.986C>G p.S329C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); catalogued as rs763039737, COSV55319066, COSV55332717; called by muse, mutect2, varscan2
- HMGCS1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.108); catalogued as COSV57289934; called by muse, mutect2, varscan2
- HSD3B7 | c.838G>T p.G280* | Nonsense Mutation (SNP) | VAF 127/210 reads (60%) | catalogued as COSV52680032, COSV52680306; called by muse, mutect2, varscan2
- IFIH1 | c.2770G>C p.E924Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55126140; called by muse, mutect2, varscan2
- IGSF11 | c.1228A>T p.T410S (on ENST00000393775 / NM_001015887.3; = p.T409S on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV61168514; called by muse, mutect2, varscan2
- INTS6L | c.270G>C p.Q90H | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.048); catalogued as COSV66084196; called by muse, mutect2, varscan2
- JPH2 | c.1055G>T p.R352L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV65902940; called by muse, mutect2, varscan2
- KEAP1 | c.756G>T p.W252C | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50274462, COSV50300442; called by muse, mutect2, varscan2
- KRT10 | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.329); catalogued as rs763011311, COSV54089343; called by muse, mutect2, varscan2
- KRT17 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as rs374932182; called by muse, mutect2, varscan2
- KRTAP1-1 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748281420, COSV60397848, COSV60398278; called by muse, mutect2, varscan2
- LIN28B | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61494418; called by muse, mutect2
- LPA | c.209+1G>A p.X70_splice | Splice Site (SNP) | VAF 70/172 reads (41%) | catalogued as rs533200556, COSV60300564; called by muse, mutect2, varscan2
- LRRC4B | c.1682C>T p.T561M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.673); catalogued as COSV65349702; called by muse, mutect2, varscan2
- LRRIQ3 | c.872T>C p.I291T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.203); catalogued as COSV63040669; called by muse, mutect2, varscan2
- LZTS1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.862); catalogued as rs781698128, COSV56116512; called by muse, mutect2, varscan2
- MADD | c.3457G>C p.E1153Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.405); catalogued as COSV60622961; called by muse, mutect2, varscan2
- MAP1LC3C | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.039); catalogued as COSV61803633; called by muse, mutect2, varscan2
- MBD1 | c.833T>C p.M278T | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV54000250; called by muse, mutect2, varscan2
- MED12 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.737); catalogued as COSV100379840, COSV61337091; called by muse, mutect2, varscan2
- MEGF8 | c.4830G>A p.K1610= (on ENST00000251268 / NM_001271938.2; = p.K1543= on NM_001410.3) | Splice Region (SNP) | VAF 6/15 reads (40%) | catalogued as rs1346562564, COSV52081355; called by muse, mutect2, varscan2
- MLH1 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs1485929020, COSV51616857; called by muse, mutect2, varscan2
- MLLT10 | c.2062C>G p.R688G (on ENST00000307729 / NM_001195626.3; = p.R704G on NM_004641.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV56994436; called by muse, mutect2, varscan2
- MS4A3 | c.611G>C p.R204T | Missense Mutation (SNP) | VAF 103/176 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV53935489, COSV53936936; called by muse, mutect2, varscan2
- MSL3 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV56492612; called by muse, mutect2, varscan2
- MTA1 | c.97-1G>C p.X33_splice | Splice Site (SNP) | VAF 22/80 reads (28%) | catalogued as COSV58756775; called by muse, mutect2, varscan2
- MYOCD | c.2761G>C p.D921H | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58501987; called by muse, mutect2
- MYPN | c.3301C>T p.P1101S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.077); catalogued as COSV62733108; called by muse, mutect2, varscan2
- NCAM1 | c.335T>C p.V112A | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100377997; called by muse, mutect2, varscan2
- NINJ2 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV56751703; called by muse, mutect2, varscan2
- NTRK3 | c.2185C>T p.H729Y (on ENST00000360948 / NM_001012338.2; = p.H715Y on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62301086, COSV62306579; called by muse, mutect2
- OR2H2 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs773530562, COSV63542045; called by muse, mutect2, varscan2
- OR4X2 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 83/293 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs1277938109, COSV56583046; called by muse, mutect2, varscan2
- OR51Q1 | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV56178534; called by muse, mutect2, varscan2
- OR5M10 | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 61/97 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV73242292; called by muse, mutect2, varscan2
- OR6N2 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.133); catalogued as COSV59411033; called by muse, mutect2, varscan2
- OSBPL9 | c.1550T>C p.I517T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV61868674; called by muse, mutect2, varscan2
- OTOR | c.273G>T p.Q91H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.203); catalogued as COSV55721945; called by muse, mutect2, varscan2
- OXNAD1 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53266450; called by muse, mutect2, varscan2
- PABPC5 | c.656T>C p.F219S | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763059925, COSV57040128; called by muse, mutect2, varscan2
- PAX2 | c.663G>C p.L221F | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100695484, COSV62290940; called by muse, mutect2, varscan2
- PCDH15 | c.4805A>G p.N1602S (on ENST00000644397 / NM_001354429.2; = p.N1544S on NM_001142771.2) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.55); PolyPhen probably damaging (0.994); catalogued as COSV64688139; called by muse, mutect2, varscan2
- PCDHGA1 | c.1234A>T p.R412* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as COSV65295977; called by muse, mutect2, varscan2
- PCED1A | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV62313553; called by muse, mutect2, varscan2
- PCNT | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV64027191; called by muse, mutect2, varscan2
- PDE6B | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.03); catalogued as rs144664551, COSV55325577; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDLIM5 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58747015; called by muse, mutect2, varscan2
- PHOX2A | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53354692, COSV53354794; called by muse, mutect2, varscan2
- PICK1 | c.456G>T p.R152S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as COSV63660044; called by muse, mutect2, varscan2
- PLCL1 | c.839T>C p.I280T | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV70826517; called by muse, mutect2, varscan2
- PLPPR4 | c.1020C>A p.H340Q | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV64565386; called by muse, varscan2
- PLPPR4 | c.1065C>A p.N355K | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0.021); catalogued as COSV64565394; called by muse, varscan2
- PLPPR4 | c.2058G>C p.K686N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100926965, COSV64565403; called by muse, mutect2, varscan2
- PRCP | c.1385A>G p.K462R | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100476245, COSV57288371; called by muse, mutect2, varscan2
- PRDM1 | c.1952G>C p.R651P | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64845060, COSV64845329; called by muse, mutect2, varscan2
- PRDM9 | c.1142G>A p.R381K | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.121); catalogued as COSV57005274; called by muse, mutect2, varscan2
- PRUNE2 | c.6637G>C p.D2213H | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV65040561; called by muse, mutect2, varscan2
- PTPRG | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV55637217; called by muse, mutect2, varscan2
- RHCE | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV53799606; called by muse, mutect2, varscan2
- RNF10 | c.1606A>T p.R536W | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as rs774057953, COSV58044664; called by muse, mutect2, varscan2
- RNF141 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV56416634; called by muse, mutect2
- RTP1 | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.2); PolyPhen benign (0.328); catalogued as COSV100398757, COSV56618201; called by muse, mutect2, varscan2
- SCAI | c.72G>C p.E24D | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV60611993; called by muse, mutect2
- SCN1A | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as rs374317182; called by muse, mutect2, varscan2
- SEMA6B | c.1405T>C p.S469P | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.351); catalogued as COSV56703336; called by muse, mutect2, varscan2
- SERPINA12 | c.837G>T p.K279N | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as COSV57943183; called by muse, mutect2, varscan2
- SGCB | c.905G>T p.S302I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as rs759466020, COSV67340874; called by muse, mutect2, varscan2
- SGCE | c.1215G>C p.K405N (on ENST00000647096; = p.K369N on NM_003919.3) | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.427); catalogued as rs968874667, COSV56016572, COSV56017424, COSV99722006; called by muse, mutect2
- SIPA1L1 | c.3602C>T p.T1201M | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs753081355, COSV62169577; called by muse, mutect2, varscan2
- SKP2 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs776151084, COSV57041404; called by muse, mutect2, varscan2
- SLC4A1AP | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.034); catalogued as rs1344872887, COSV58134458; called by muse, mutect2, varscan2
- SLITRK4 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs997536820, COSV100567547, COSV62023284; called by muse, mutect2, varscan2
- SORL1 | c.4820G>C p.S1607T | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.995); catalogued as COSV52752730; called by muse, mutect2, varscan2
- SPEN | c.5323G>A p.E1775K | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs766847660, COSV65360618; called by muse, mutect2, varscan2
- SPRTN | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs201636359, COSV50477998; called by muse, mutect2, varscan2
- SSH2 | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.185); catalogued as rs1418794646, COSV52170865; called by muse, mutect2, varscan2
- ST6GAL2 | c.196C>A p.H66N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | PolyPhen benign (0.023); catalogued as COSV64527686; called by muse, mutect2, varscan2
- SUV39H2 | c.455G>A p.G152E (on ENST00000354919 / NM_001193424.2; = p.G92E on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57953592; called by muse, mutect2, varscan2
- TAGLN2 | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV57422051; called by muse, mutect2, varscan2
- TAS2R40 | c.406A>T p.R136W | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV68818308; called by muse, mutect2, varscan2
- TG | c.111G>C p.Q37H | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV55072746; called by muse, mutect2, varscan2
- TG | c.295C>A p.Q99K | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as COSV55072760; called by muse, mutect2
- THRA | c.982+2T>C p.X328_splice | Splice Site (SNP) | VAF 13/284 reads (5%) | catalogued as COSV52842184; called by muse, mutect2
- TMEM143 | c.830A>G p.Q277R | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.111); catalogued as rs1190563898, COSV53156076; called by muse, mutect2
- TNS2 | c.1195C>A p.P399T (on ENST00000314250 / NM_170754.4; = p.P409T on NM_015319.2) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs984661297, COSV58576668; called by muse, mutect2, varscan2
- TRDV2 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as rs760502971; called by muse, varscan2
- TRIOBP | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.639); catalogued as rs750849895, COSV60376246; called by muse, varscan2
- TRO | c.3612C>A p.S1204R | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV51500364; called by muse, mutect2, varscan2
- TRPA1 | c.623C>G p.S208* | Nonsense Mutation (SNP) | VAF 26/49 reads (53%) | catalogued as COSV51559680; called by muse, mutect2, varscan2
- TTN | c.58753G>C p.D19585H (on ENST00000591111; = p.D12161H on NM_003319.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | PolyPhen probably damaging (0.999); catalogued as COSV59994825; called by mutect2, varscan2
- UBE2C | c.420A>G p.G140= | Splice Region (SNP) | VAF 13/98 reads (13%) | catalogued as COSV54754825; called by muse, mutect2, varscan2
- UBR5 | c.8088C>A p.F2696L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55284737; called by muse, varscan2
- UGT1A9 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs372244167, COSV60836467; called by muse, mutect2, varscan2
- UNC5D | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54786882; called by muse, mutect2
- USP15 | c.1595G>A p.R532K (on ENST00000280377 / NM_001351159.2; = p.R503K on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV54790927; called by muse, mutect2, varscan2
- USP29 | c.627C>G p.N209K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54141843, COSV54141847; called by muse, mutect2, varscan2
- USPL1 | c.838C>G p.L280V | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV54999560; called by muse, mutect2, varscan2
- WDR45 | c.596C>T p.S199F (on ENST00000376372 / NM_001029896.2; = p.S200F on NM_007075.3) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100540238, COSV59875868; called by muse, mutect2, varscan2
- WDR70 | c.27G>A p.V9= | Splice Region (SNP) | VAF 33/105 reads (31%) | catalogued as COSV54271059; called by muse, mutect2, varscan2
- WWC1 | c.513C>T p.V171= | Splice Region (SNP) | VAF 10/42 reads (24%) | catalogued as COSV54649588; called by muse, mutect2, varscan2
- ZFAND4 | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60858666; called by muse, mutect2, varscan2
- ZFP14 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 58/85 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as COSV54201951; called by muse, mutect2, varscan2
- ZNF142 | c.2137A>C p.M713L (on ENST00000411696 / NM_001379660.1; = p.M513L on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV68743462; called by muse, mutect2, varscan2
- ZNF184 | c.550G>T p.G184W | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV53003969; called by muse, mutect2, varscan2
- ZNF292 | c.2882G>A p.G961D | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV60538323; called by muse, mutect2, varscan2
- ZNF544 | c.1197G>C p.Q399H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.314); catalogued as COSV54135501; called by muse, mutect2, varscan2
- ZSWIM2 | c.308A>G p.E103G | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54574903; called by muse, mutect2, varscan2
- CEP68 | c.208dup p.T70Nfs*2 | Frame Shift Ins (INS) | VAF 51/120 reads (43%) | called by mutect2, pindel, varscan2
- GAGE2A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 145/1784 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- GRHL2 | c.1566dup p.G523Wfs*25 | Frame Shift Ins (INS) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- IGLV3-22 | c.163C>A p.Q55K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2
- OR14A16 | c.111_125del p.M38_L42del | In Frame Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RORB | c.1195dup p.I399Nfs*16 (on ENST00000396204 / NM_001365023.1; = p.I388Nfs*16 on NM_006914.4) | Frame Shift Ins (INS) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- SYNRG | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 130/707 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ABCC9 | c.2577G>T p.L859= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV53968369; called by muse, mutect2
- ADAMTSL2 | c.2637G>A p.K879= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs1390561048; called by muse, mutect2, varscan2
- ADCY1 | c.1179G>C p.L393= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV52033238; called by muse, mutect2
- ADGRB1 | c.3123G>T p.T1041= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV60094979; called by muse, mutect2, varscan2
- AKAP9 | c.6165G>A p.V2055= (on ENST00000359028; = p.V2023= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV62343741; called by muse, mutect2, varscan2
- ANO7 | c.750C>T p.F250= (on ENST00000274979; = p.F196= on NM_001370694.2) | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs1559443923, COSV51470753; called by muse, mutect2, varscan2
- AOX1 | c.2967G>A p.R989= | Silent (SNP) | VAF 23/163 reads (14%) | catalogued as COSV65981143; called by muse, mutect2, varscan2
- CCT8L2 | c.900C>T p.D300= | Silent (SNP) | VAF 69/252 reads (27%) | catalogued as rs772533950, COSV63462162; called by muse, varscan2
- CRP | c.456C>T p.I152= | Silent (SNP) | VAF 132/426 reads (31%) | catalogued as COSV54812674; called by muse, mutect2, varscan2
- CSMD3 | c.7987C>A p.R2663= (on ENST00000297405 / NM_001363185.1; = p.R2559= on NM_052900.3) | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV52100177, COSV52156018; called by muse, mutect2, varscan2
- CTIF | c.1455C>T p.F485= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs751496412, COSV56482425; called by muse, mutect2, varscan2
- CYB561 | c.633C>T p.F211= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs779395351, COSV62539657; called by mutect2, varscan2
- D2HGDH | c.1074G>A p.L358= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV58320284; called by muse, mutect2, varscan2
- DNAH3 | c.7395A>G p.A2465= | Silent (SNP) | VAF 31/45 reads (69%) | catalogued as rs751943109, COSV54516153; called by muse, mutect2, varscan2
- ECPAS | c.4674A>G p.P1558= | Silent (SNP) | VAF 86/184 reads (47%) | catalogued as rs771259015, COSV52195665; called by muse, mutect2, varscan2
- EIF4G3 | c.567C>T p.P189= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs1406409937, COSV51673709; called by muse, mutect2, varscan2
- EPB41L3 | c.69G>T p.A23= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs763808085, COSV59450444; called by muse, mutect2, varscan2
- FRG2 | c.669C>A p.T223= | Silent (SNP) | VAF 6/31 reads (19%) | called by mutect2, varscan2
- GAB4 | c.294C>T p.L98= | Silent (SNP) | VAF 89/264 reads (34%) | catalogued as rs556110776, COSV68753571; called by muse, mutect2, varscan2
- GALNT14 | c.888G>A p.G296= | Silent (SNP) | VAF 56/78 reads (72%) | catalogued as COSV61104298; called by muse, mutect2, varscan2
- GHRH | c.39C>T p.L13= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs1487325091, COSV52902417; called by muse, mutect2, varscan2
- HOXB2 | c.546C>T p.L182= | Silent (SNP) | VAF 31/242 reads (13%) | catalogued as COSV57486518; called by muse, mutect2, varscan2
- HPS4 | c.774C>T p.L258= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV61103184; called by muse, mutect2, varscan2
- HRH2 | c.81C>T p.V27= | Silent (SNP) | VAF 78/224 reads (35%) | catalogued as COSV51573763, COSV51575877; called by muse, mutect2, varscan2
- IDNK | c.357C>G p.L119= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV52891368; called by muse, mutect2, varscan2
- ISLR2 | c.423C>T p.D141= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as COSV62301957; called by muse, mutect2
- KIRREL1 | c.1857A>G p.A619= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV63286427; called by muse, mutect2, varscan2
- KRIT1 | c.1536G>A p.V512= | Silent (SNP) | VAF 84/182 reads (46%) | catalogued as COSV60667606, COSV60668122; called by muse, mutect2, varscan2
- KRTAP26-1 | c.180C>T p.C60= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as rs759084373, COSV62128642; called by muse, mutect2, varscan2
- MC3R | c.33G>A p.Q11= | Silent (SNP) | VAF 85/264 reads (32%) | catalogued as COSV54763533; called by muse, mutect2, varscan2
- MTHFSD | c.1053C>T p.D351= (on ENST00000360900 / NM_001159377.2; = p.D350= on NM_022764.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV59802820; called by muse, mutect2, varscan2
- MYO15A | c.6675C>T p.D2225= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs377161484; called by muse, mutect2, varscan2
- NLRP7 | c.120G>A p.K40= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV60173270; called by muse, mutect2, varscan2
- NRXN1 | c.4182C>T p.I1394= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV60486642; called by muse, mutect2, varscan2
- OR2G6 | c.717G>A p.G239= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs779028414, COSV58574160; called by muse, mutect2, varscan2
- OR4K14 | c.531C>T p.S177= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV59292580; called by muse, mutect2, varscan2
- OR4M1 | c.204C>A p.L68= | Silent (SNP) | VAF 73/564 reads (13%) | catalogued as COSV60060579; called by muse, mutect2, varscan2
- OR4S2 | c.414A>T p.T138= | Silent (SNP) | VAF 101/161 reads (63%) | catalogued as COSV56746529; called by muse, mutect2, varscan2
- OR51B5 | c.138C>T p.L46= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV56175703; called by muse, mutect2, varscan2
- OR52B4 | c.720C>G p.L240= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV68768805; called by muse, mutect2, varscan2
- PCDH7 | c.2886G>A p.Q962= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV62338117; called by muse, mutect2, varscan2
- PCDHB11 | c.2079G>A p.A693= | Silent (SNP) | VAF 94/220 reads (43%) | catalogued as rs373740953, COSV61310974; called by muse, mutect2, varscan2
- PDPR | c.903G>T p.L301= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV55350961; called by muse, mutect2, varscan2
- PENK | c.546G>C p.V182= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as COSV59240954; called by muse, mutect2, varscan2
- PHYKPL | c.1041C>T p.L347= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs1031509017, COSV57423774; called by muse, mutect2, varscan2
- PNPLA3 | c.357C>T p.T119= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV53377935; called by muse, mutect2, varscan2
- POU3F1 | c.1140G>A p.K380= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100884675, COSV65948788; called by muse, mutect2, varscan2
- PRAMEF2 | c.687G>A p.K229= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as rs754701755, COSV53574591; called by muse, mutect2, varscan2
- PROS1 | c.864C>T p.C288= | Silent (SNP) | VAF 41/152 reads (27%) | catalogued as rs554787241, CM051207, COSV67775047; called by muse, mutect2, varscan2
- PSMD14 | c.513A>C p.G171= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV68832215; called by muse, mutect2, varscan2
- PTER | c.717A>G p.K239= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as COSV54345371; called by muse, mutect2
- PTPRO | c.2289G>A p.Q763= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV55508125; called by muse, mutect2, varscan2
- RABEP2 | c.1635T>C p.A545= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs1450357404, COSV62869092; called by muse, mutect2, varscan2
- RBM34 | c.381G>A p.A127= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs750852075, COSV64012645; called by muse, mutect2, varscan2
- RNF139 | c.879C>T p.G293= | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as COSV52678973; called by muse, mutect2
- SLC29A3 | c.1095C>T p.L365= | Silent (SNP) | VAF 32/183 reads (17%) | catalogued as COSV64384877; called by muse, mutect2, varscan2
- SLC52A2 | c.615C>T p.V205= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs549377529, COSV57351595; called by muse, mutect2, varscan2
- SNX13 | c.312C>T p.L104= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV68064645; called by muse, mutect2, varscan2
- SNX14 | c.2184C>T p.F728= (on ENST00000314673 / NM_001350535.1; = p.F675= on NM_020468.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs768943319, COSV59011226, COSV59016315; called by muse, mutect2, varscan2
- SPEG | c.2658C>T p.V886= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV56667103; called by muse, mutect2
- SPHKAP | c.123C>T p.I41= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as rs1198852312, COSV60875563; called by muse, mutect2, varscan2
- TAF3 | c.1317C>T p.S439= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as rs1454045453, COSV60205450; called by muse, mutect2, varscan2
- TBL1X | c.1530C>T p.S510= | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as rs139999402, COSV54278549; called by muse, mutect2, varscan2
- TECTA | c.3315C>T p.Y1105= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs142573400; ClinVar: likely benign; called by mutect2, varscan2
- THRA | c.645C>T p.F215= | Silent (SNP) | VAF 9/162 reads (6%) | catalogued as COSV52842172; called by muse, mutect2
- THRB | c.864A>G p.K288= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV54979847; called by muse, mutect2
- TMEM132D | c.2034C>T p.L678= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV67159887; called by muse, mutect2, varscan2
- TMEM132E | c.468C>T p.F156= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as rs1268615251, COSV58700184; called by muse, mutect2, varscan2
- TMEM94 | c.786G>T p.L262= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV58594909; called by muse, mutect2, varscan2
- TRIM4 | c.1254G>T p.A418= | Silent (SNP) | VAF 91/1147 reads (8%) | catalogued as COSV62468834, COSV62470689; called by muse, mutect2
- TRPM3 | c.3723G>A p.E1241= (on ENST00000357533 / NM_001366142.2; = p.E1096= on NM_020952.6) | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV62584419; called by muse, mutect2, varscan2
- TRPM6 | c.2029C>T p.L677= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV62507627; called by muse, mutect2
- UGT2B7 | c.1386C>T p.F462= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV59442926; called by muse, mutect2, varscan2
- UNC45A | c.276C>G p.V92= | Silent (SNP) | VAF 48/126 reads (38%) | catalogued as COSV57745941; called by muse, mutect2, varscan2
- UPRT | c.291A>G p.L97= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as COSV64912265; called by muse, mutect2, varscan2
- VPS54 | c.1353C>G p.L451= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs373361920, COSV55438450; called by muse, mutect2, varscan2
- XKR6 | c.84C>T p.G28= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1295192770, COSV52008105; called by muse, mutect2, varscan2
- ZNF175 | c.699C>T p.F233= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs1236607980, COSV51795036; called by muse, mutect2, varscan2
- ZNF423 | c.405C>T p.L135= (on ENST00000563137 / NM_001379286.1; = p.L127= on NM_015069.4) | Silent (SNP) | VAF 30/46 reads (65%) | catalogued as rs746399268, COSV52185170; called by muse, mutect2, varscan2
- ZNF658 | c.12T>G p.S4= | Silent (SNP) | VAF 32/184 reads (17%) | called by muse, mutect2, varscan2
- ZNF831 | c.1476C>G p.L492= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as COSV64039230; called by muse, mutect2, varscan2
- ZSCAN1 | c.873C>T p.P291= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV56603619; called by muse, mutect2
- ACAD9 | c.*205A>T | 3'UTR (SNP) | VAF 31/46 reads (67%) | catalogued as COSV100459271; called by muse, mutect2, varscan2
- BIRC8 | n.1565G>C | RNA (SNP) | VAF 23/72 reads (32%) | catalogued as COSV58843149; called by muse, mutect2, varscan2
- C15orf54 | n.879G>A | RNA (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- CORT | c.-133C>T | 5'UTR (SNP) | VAF 33/148 reads (22%) | catalogued as rs1368945400, COSV57630552; called by muse, mutect2, varscan2
- HMGB1P1 | n.267C>G | RNA (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- ITGA3 | c.*93T>C | 3'UTR (SNP) | VAF 85/293 reads (29%) | catalogued as COSV99143797; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.957T>G | RNA (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- PRDM15 | c.-3G>C | 5'UTR (SNP) | VAF 29/49 reads (59%) | catalogued as COSV54151335; called by muse, mutect2, varscan2
- RRM2 | n.452A>G | RNA (SNP) | VAF 24/137 reads (18%) | called by muse, mutect2, varscan2
